CPTAC case C3L-04731 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7a313a73-4463-4c42-b8b6-1e045134fc99

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Parietal lobe; Age at diagnosis: 65.1 years (23,774 days); Year of diagnosis: 2018; Days to last known disease status: 1,513 days (4.1 years); Days to last follow up: 1,513 days (4.1 years).
   Pathology details: Greatest tumor dimension: 4 cm.

Follow-up (5 entries)
- Days to follow up: 389 days (1.1 years); Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 738 days (2.0 years); Disease response: Progressive Disease; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 738 days (2.0 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 987 days (2.7 years); Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,513 days (4.1 years); Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 95 kg; Height: 167 cm; BMI: 34.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04731-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 259 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04731-25: Section location: Parietal Lobe; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3L-04731-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
